Somatic mutation profile of tumor specimen MMRF_2815_1_BM_CD138pos (aliquot MMRF_2815_1_BM_CD138pos_T1_KHS5U_L15701) from MMRF case MMRF_2815, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,932 days).
Specimen MMRF_2815_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 932b483d-a7aa-4c44-bff1-2222377a5cc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2815_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2815_1_PB_WBC_C3_KHS5U_L15747; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f3de66f-1e8f-4dda-a373-5d0d1bc8ad73

The open-access MAF lists 100 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 25, Silent 10, Intron 9, 3'Flank 3, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*1005A>C | 3'UTR (SNP) | VAF 29/187 reads (16%) | catalogued as rs121913105, CM074175, CM990596, CX140380, COSV53391370, COSV53394867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCER1 | c.858T>G p.D286E | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs11105882, COSV62647212; called by muse, mutect2, varscan2
- CLASRP | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.05); catalogued as rs1459789914; called by muse, mutect2, varscan2
- DNAH9 | c.9103C>T p.R3035C | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201172849; called by muse, mutect2
- FAM120B | c.2040A>G p.I680M | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs1238070786; called by muse, mutect2, varscan2
- FBXL17 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs368164862; called by muse, mutect2, varscan2
- GART | c.1346T>C p.M449T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201912693; called by muse, mutect2, varscan2
- GGA2 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.854); catalogued as rs1567363617, COSV59168952; called by muse, mutect2, varscan2
- GUCY1A2 | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV56502436, COSV56503210; called by muse, mutect2, varscan2
- H1-4 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as rs553325174, COSV56801266, COSV56802449; called by muse, mutect2, varscan2
- IGHV2-70D | c.316A>C p.M106L | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.42); PolyPhen benign (0.073); catalogued as rs1310513170; called by muse, mutect2, varscan2
- ITGA6 | c.1904G>A p.R635Q (on ENST00000442250; = p.R596Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.047); catalogued as rs750020736; called by muse, mutect2, varscan2
- LARP1B | c.1255A>T p.I419F | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1185403364; called by muse, mutect2, varscan2
- LTN1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 107/256 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV63734912; called by muse, mutect2, varscan2
- MGAT3 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 16/431 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1307905487; called by muse, mutect2
- TMEM205 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs747874854; called by muse, mutect2, varscan2
- YOD1 | c.601A>G p.I201V | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs750884001; called by muse, mutect2
- ZAN | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 46/435 reads (11%) | catalogued as COSV61806790, COSV61818410; called by muse, mutect2, varscan2
- ACTR3B | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ADARB2 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY8 | c.3218G>A p.S1073N | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ASTN1 | c.2800C>A p.H934N | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- CABP7 | c.562_563del p.L189Hfs*168 | Frame Shift Del (DEL) | VAF 60/226 reads (27%) | called by pindel, varscan2
- CAPN15 | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHD8 | c.4071T>A p.F1357L (on ENST00000646647 / NM_001170629.2; = p.F1078L on NM_020920.4) | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CXCL3 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ELP1 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2
- EPHA3 | c.1136A>G p.N379S | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IGHV2-70D | c.153T>G p.S51R | Missense Mutation (SNP) | VAF 77/87 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, varscan2
- IGLV3-9 | c.62_66del p.Y21Sfs*27 | Frame Shift Del (DEL) | VAF 35/157 reads (22%) | called by mutect2, pindel, varscan2
- KNTC1 | c.2216A>C p.K739T | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); called by muse, mutect2
- MCTP1 | c.1601A>G p.D534G | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- MGAT4C | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- MYH10 | c.5054T>G p.L1685R | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- NAA35 | c.1812A>C p.K604N | Missense Mutation (SNP) | VAF 134/291 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NELFB | c.1876G>T p.A626S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NXPE2 | c.139T>G p.F47V | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOG | c.3534T>A p.S1178R | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCLO | c.13577A>G p.H4526R | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- PCLO | c.4059G>T p.Q1353H | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHF21A | c.1658A>T p.H553L (on ENST00000418153 / NM_001101802.3; = p.H507L on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- POSTN | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RINT1 | c.1303T>C p.F435L | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ROBO3 | c.1056G>T p.Q352H | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); called by muse, mutect2
- SETD2 | c.2246C>T p.T749I | Missense Mutation (SNP) | VAF 11/283 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- SFMBT1 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- TRIM49B | c.65T>A p.F22Y | Missense Mutation (SNP) | VAF 5/144 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- UGT2B10 | c.656T>G p.F219C | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- YDJC | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ZFP64 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 28/210 reads (13%) | called by muse, mutect2, varscan2
- ELAVL2 | c.1011C>G p.L337= | Silent (SNP) | VAF 206/432 reads (48%) | called by muse, mutect2, varscan2
- GNPTAB | c.57G>A p.G19= | Silent (SNP) | VAF 69/156 reads (44%) | called by muse, mutect2, varscan2
- GPRIN2 | c.147G>A p.Q49= | Silent (SNP) | VAF 59/297 reads (20%) | called by muse, mutect2, varscan2
- H1-4 | c.339T>G p.S113= | Silent (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.108C>G p.T36= | Silent (SNP) | VAF 54/59 reads (92%) | called by muse, varscan2
- OR9Q2 | c.264C>T p.H88= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as rs761516412, COSV100285496; called by muse, mutect2
- PLXND1 | c.4359C>T p.H1453= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as rs780259165; called by muse, mutect2, varscan2
- TRANK1 | c.2244G>A p.Q748= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- TRIM49B | c.66C>T p.F22= | Silent (SNP) | VAF 5/146 reads (3%) | called by muse, mutect2
- TTN | c.69390A>G p.S23130= (on ENST00000591111; = p.S15706= on NM_003319.4) | Silent (SNP) | VAF 95/205 reads (46%) | catalogued as rs1274344074; called by muse, mutect2, varscan2
- AC112695.1 | n.289T>C | RNA (SNP) | VAF 4/67 reads (6%) | catalogued as rs1263373213; called by muse, mutect2
- ARC | c.*132G>A | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- ATP13A2 | c.1307-12C>T | Intron (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
- BMP6 | c.*918G>A | 3'UTR (SNP) | VAF 10/94 reads (11%) | catalogued as rs373381483; called by muse, mutect2, varscan2
- BORCS7 | c.*477C>T | 3'UTR (SNP) | VAF 37/75 reads (49%) | catalogued as rs1264615593; called by muse, mutect2, varscan2
- BRAT1 | c.924-97C>T | Intron (SNP) | VAF 96/180 reads (53%) | called by muse, mutect2, varscan2
- CDCA8 | c.*80T>C | 3'UTR (SNP) | VAF 120/280 reads (43%) | called by muse, mutect2, varscan2
- CERS6 | c.*3664T>C | 3'UTR (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- CPNE8 | c.1144-65T>G | Intron (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2
- DCUN1D3 | c.*305G>T | 3'UTR (SNP) | VAF 31/50 reads (62%) | catalogued as rs1165163240; called by muse, mutect2, varscan2
- EXOSC4 | chr8:144082602 T>C | 3'Flank (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- FAM234B | c.*657T>C | 3'UTR (SNP) | VAF 56/110 reads (51%) | called by muse, mutect2, varscan2
- FEZ1 | c.*404G>A | 3'UTR (SNP) | VAF 18/32 reads (56%) | catalogued as rs542716708; called by muse, varscan2
- GABRG2 | c.1249-728A>G | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2
- HYAL2 | c.-47+752G>A | Intron (SNP) | VAF 76/147 reads (52%) | called by muse, mutect2, varscan2
- KIF1A | c.*1597C>T | 3'UTR (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- LUC7L2 | c.809+57T>G | Intron (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- MCMDC2 | c.*474C>G | 3'UTR (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- METTL15 | c.*1088T>G | 3'UTR (SNP) | VAF 79/196 reads (40%) | called by muse, mutect2, varscan2
- METTL15 | c.*2216A>G | 3'UTR (SNP) | VAF 61/175 reads (35%) | catalogued as rs1383123518; called by muse, mutect2, varscan2
- MSRB3 | c.*3216T>G | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1539G>A | 3'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- NPAS2 | c.1283-77C>T | Intron (SNP) | VAF 8/172 reads (5%) | catalogued as rs982547362; called by muse, mutect2
- PALM2AKAP2 | chr9:110171054 C>T | 3'Flank (SNP) | VAF 38/149 reads (26%) | called by muse, mutect2, varscan2
- PAX6 | c.-51-17T>G | Intron (SNP) | VAF 66/133 reads (50%) | called by muse, mutect2, varscan2
- PEDS1 | c.*647C>T | 3'UTR (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- PHACTR2 | c.*3705T>G | 3'UTR (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- PIK3CD | c.*1614A>G | 3'UTR (SNP) | VAF 166/320 reads (52%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.*1433A>C | 3'UTR (SNP) | VAF 53/115 reads (46%) | called by muse, mutect2, varscan2
- REPS1 | c.-560T>C | 5'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2
- RHOBTB2 | c.*2408G>A | 3'UTR (SNP) | VAF 74/163 reads (45%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-848A>G | Intron (SNP) | VAF 94/219 reads (43%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.*1763G>C | 3'UTR (SNP) | VAF 148/304 reads (49%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-3641C>T | 5'UTR (SNP) | VAF 12/172 reads (7%) | catalogued as rs185733717; called by muse, mutect2
- SPOP | c.*1376T>C | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- SPRY4 | c.*3088T>C | 3'UTR (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- SYBU | chr8:109645200 G>A | 5'Flank (SNP) | VAF 77/161 reads (48%) | called by muse, mutect2, varscan2
- SYNCRIP | chr6:85610662 C>G | 3'Flank (SNP) | VAF 17/109 reads (16%) | called by mutect2, varscan2
- SYT11 | c.*2463C>T | 3'UTR (SNP) | VAF 33/198 reads (17%) | called by muse, mutect2, varscan2
- UBE4A | c.*2730del | 3'UTR (DEL) | VAF 52/312 reads (17%) | called by mutect2, pindel, varscan2
